Gene-level copy-number profile of tumor specimen BLGSP-71-32-00697-01A from CGCI case BLGSP-71-32-00697, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 43.5 years (15,903 days).
Specimen BLGSP-71-32-00697-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fc393bc0-b984-4ae1-b923-3cd8a7764ad6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-32-00697-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,312 have no estimate.
https://portal.gdc.cancer.gov/files/9a41cba0-4ec3-432f-a477-fddf0b699a38

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 123; copy number 1: 4,036; copy number 2: 46,931; copy number 3: 6,269; copy number 4: 680; copy number 5: 231; copy number 6: 27; copy number 7: 3; copy number 8: 1; copy number 9: 5; copy number 10: 2; copy number 11: 2; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:8,558,725–8,619,761, 2 genes: GPR78, CPZ.
- chr14:105,672,308–106,481,706, 119 genes (within-gene range 0–5) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–5): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 272 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:23,549,139–23,640,568, 4 genes, copy number 5: AL021154.1, ID3, AL450043.1, MDS2.
- chr1:160,400,564–160,647,295, 5 genes, copy number 5: VANGL2, SLAMF6, AL138930.1, CD84, SLAMF1.
- chr1:198,597,724–198,757,476, 4 genes, copy number 6: AL157402.1, PTPRC, AL157402.2, PEBP1P3.
- chr1:198,973,379–199,080,975, 4 genes, copy number 5: AC096631.1, LINC01222, LINC01221, AC105941.1.
- chr2:37,325,340–37,373,322, 3 genes, copy number 5: AC007391.1, RNU6-939P, QPCT.
- chr2:64,092,652–64,252,859, 4 genes, copy number 5: PELI1, AC012368.1, LINC00309, AC012368.3.
- chr2:89,319,625–90,235,370, 35 genes, copy number 5–10 (within-gene range 5–52): IGKV1-39, IGKV2-40, 5S_rRNA, IGKV2D-40, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV3D-34, IGKV1D-33, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7.
- chr2:136,077,892–136,233,245, 4 genes, copy number 5: AC068492.1, CXCR4, HNRNPKP2, AC112255.1.
- chr2:144,517,978–144,521,477, 4 genes, copy number 5 (within-gene range 4–5): ZEB2-AS1, AC009951.2, AC009951.1, AC009951.3.
- chr2:196,133,583–196,176,503, 2 genes, copy number 5: STK17B, AC114760.2.
- chr2:213,152,970–213,167,712, 2 genes, copy number 6: AC079610.1, LINC01953.
- chr3:16,802,651–17,090,604, 2 genes, copy number 5 (within-gene range 4–5): PLCL2, MIR3714.
- chr3:71,567,863–71,574,457, 2 genes, copy number 5 (within-gene range 3–5): AC097634.2, FOXP1-IT1.
- chr5:158,485,190–159,099,916, 4 genes, copy number 5: AC091939.1, EBF1, AC136424.2, AC136424.1.
- chr6:25,061,796–25,181,745, 4 genes, copy number 5 (within-gene range 4–5): AL133268.4, AL133268.1, AL590084.3, AL590084.1.
- chr6:90,073,051–90,363,912, 4 genes, copy number 5–6: AL158136.1, AL117342.1, AL132996.1, MIR4464.
- chr7:24,796,540–24,981,634, 2 genes, copy number 6: OSBPL3, SNRPCP19.
- chr7:30,284,597–30,504,841, 9 genes, copy number 5 (within-gene range 4–5): ZNRF2, MIR550A1, MIR550B1, AC006978.2, AC006978.1, LINC01176, NOD1, AC006027.1, GGCT.
- chr7:49,230,137–49,259,846, 2 genes, copy number 5: AC091730.1, DDX43P2.
- chr7:93,890,913–94,077,157, 8 genes, copy number 5–6 (within-gene range 3–6): TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2.
- chr7:100,177,563–100,272,218, 3 genes, copy number 5: STAG3, CASTOR3, PVRIG.
- chr7:106,035,798–106,208,267, 4 genes, copy number 5–7: AC004836.1, SYPL1, DCAF13P1, RNU6-392P.
- chr7:107,739,999–107,803,225, 3 genes, copy number 5: AC002467.1, CBLL1, SLC26A3.
- chr7:142,507,382–142,793,368, 43 genes, copy number 5 (within-gene range 3–5): TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr10:56,595,963–56,596,031, 1 gene, copy number 5: AC025039.1.
- chr10:61,901,684–62,096,944, 1 gene, copy number 5 (within-gene range 2–5): ARID5B.
- chr11:9,664,077–9,752,993, 2 genes, copy number 5: SWAP70, RN7SKP50.
- chr11:128,458,761–128,813,267, 6 genes, copy number 5: ETS1, MIR6090, ETS1-AS1, AP001122.1, FLI1, SENCR.
- chr12:10,358,464–10,410,146, 5 genes, copy number 5: LINC02598, KLRK1-AS1, KLRK1, KLRC4-KLRK1, KLRC4.
- chr12:11,649,674–11,895,377, 1 gene, copy number 5: ETV6.
- chr12:92,247,697–92,531,324, 6 genes, copy number 5: LINC02391, CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1.
- chr13:33,818,069–33,966,558, 3 genes, copy number 5: RFC3, RNU5A-4P, AL161891.1.
- chr14:62,103,122–62,130,962, 2 genes, copy number 5 (within-gene range 3–5): AL390816.2, LINC00643.
- chr14:106,482,435–106,521,073, 7 genes, copy number 5 (within-gene range 0–5): LINC00221, IGHVIV-44-1, IGHVII-44-2, IGHV1-45, IGHV1-46, IGHVII-46-1, IGHV3-47.
- chr14:106,556,936–106,879,812, 51 genes, copy number 5: IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr18:32,672,673–32,779,286, 3 genes, copy number 5: KLHL14, AC012123.1, AC012123.2.
- chr21:13,038,160–13,067,033, 2 genes, copy number 5: ANKRD30BP2, RNU6-614P.
- chr21:43,159,066–43,172,805, 2 genes, copy number 7–18: AP001631.1, CRYAA.
- chr21:43,414,483–43,479,534, 4 genes, copy number 5–11: SIK1, LINC00319, LINC00313, AP001048.1.
- chr22:18,361,820–18,391,105, 2 genes, copy number 5: FAM230J, AC011718.1.

Autosomal genes at a single copy (total copy number 1): 3,977. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
